TCGA case TCGA-BF-A1PX — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/197ac33e-d5df-40de-92f2-6ef7fe2ad6dd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 56 years; Vital status: Dead; Days to death: 282 days.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,626 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 282 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 10.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 175 cm; BMI: 25.5.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BF-A1PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 260 mg.
  Slide TCGA-BF-A1PX-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BF-A1PX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 12; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 282 days; disease-specific survival: no event (censored), 282 days; progression-free interval: no event (censored), 282 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BF-A1PX-01A-12D-A192-01): tumor purity 0.25, ploidy 1.79, whole-genome doublings 0.
